Somatic mutation profile of tumor specimen C3N-00320-02 (aliquot CPT0012370009) from CPTAC case C3N-00320, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 67.3 years (24,594 days).
Specimen C3N-00320-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9533507-f62a-4aa6-8769-6bbe01a1141d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00320-31 (Blood Derived Normal), aliquot CPT0012530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83a55b5d-9d41-4d11-a428-67ca6e840d42

The open-access MAF lists 126 somatic variants for this specimen: 88 protein-altering or splice-affecting, 23 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 23, Intron 10, Frame Shift Del 8, Nonsense Mutation 6, In Frame Del 4, 3'UTR 3, 5'UTR 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4447T>C p.C1483R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1057519914, COSV63875155; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NOTCH3 | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs28937321, CM961042; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 84/632 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.340+2T>A p.X114_splice | Splice Site (SNP) | VAF 70/183 reads (38%) | hotspot (GDC flag); catalogued as CD983001, COSV56547957, COSV56551654, COSV56551713, COSV56563827; called by muse, mutect2, varscan2
- ADGRA1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs755811625, COSV74142839; called by muse, mutect2
- AL035078.4 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs749117053; called by muse, mutect2, varscan2
- ATP13A1 | c.1297G>C p.G433R | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99366716; called by muse, mutect2, varscan2
- BECN1 | c.10T>A p.S4T | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV100831112; called by muse, mutect2, varscan2
- COL24A1 | c.3325C>A p.P1109T | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV65313975; called by muse, mutect2, varscan2
- FAM187B | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 26/203 reads (13%) | catalogued as COSV61200983; called by muse, mutect2, varscan2
- FBLN1 | c.1225C>A p.R409S | Missense Mutation (SNP) | VAF 148/555 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1218807619; called by muse, mutect2, varscan2
- HIP1R | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53441598, COSV53442271; called by muse, mutect2, varscan2
- IQGAP3 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs749818611; called by muse, mutect2, varscan2
- KIAA1671 | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1273660436, COSV64450632; called by muse, mutect2, varscan2
- MAN2B2 | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as rs757830667, COSV53450411, COSV99577991; called by muse, mutect2, varscan2
- MBD3L1 | c.575A>C p.E192A | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV59775738; called by muse, mutect2, varscan2
- NPR2 | c.740A>G p.N247S | Missense Mutation (SNP) | VAF 16/561 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0.173); catalogued as rs1193711026; called by muse, mutect2
- PCDH7 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688654; called by muse, mutect2, varscan2
- PRKG1 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773713867; called by muse, mutect2, varscan2
- RABEP2 | c.555del p.H186Mfs*28 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as COSV100706746; called by mutect2, pindel, varscan2
- SLC27A1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs1220747892, COSV53096288; called by muse, mutect2
- SPON1 | c.1101C>A p.N367K | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782513392; called by muse, mutect2
- UGT1A7 | c.671dup p.K225Qfs*9 | Frame Shift Ins (INS) | VAF 84/416 reads (20%) | catalogued as rs1476036720; called by pindel, varscan2
- VARS1 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763964925, COSV65155616; called by muse, mutect2, varscan2
- ZNF541 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV54545132; called by muse, mutect2, varscan2
- ACTR3C | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ANKDD1A | c.1425_1433del p.E475_S478delinsD | In Frame Del (DEL) | VAF 20/186 reads (11%) | called by mutect2, pindel
- APBB3 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- C2CD3 | c.3044G>A p.G1015E | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNB2 | c.1042A>G p.R348G (on ENST00000324631 / NM_201596.3; = p.R293G on NM_000724.4) | Missense Mutation (SNP) | VAF 103/424 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- CACNB2 | c.1043G>A p.R348K (on ENST00000324631 / NM_201596.3; = p.R293K on NM_000724.4) | Missense Mutation (SNP) | VAF 100/415 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.405); called by muse, varscan2
- CAMKK1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CAPS2 | c.1121del p.L374* | Frame Shift Del (DEL) | VAF 75/253 reads (30%) | called by mutect2, pindel, varscan2
- CC2D1B | c.1724C>A p.A575D | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CCDC168 | c.9328C>A p.H3110N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC96 | c.973_978del p.K325_E326del | In Frame Del (DEL) | VAF 23/79 reads (29%) | called by mutect2, pindel, varscan2
- CCL11 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CELF2 | c.1043C>G p.T348S (on ENST00000416382 / NM_001025077.3; = p.T355S on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CENPT | c.979C>A p.H327N | Missense Mutation (SNP) | VAF 50/405 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLIP1 | c.2065G>T p.A689S (on ENST00000620786 / NM_001247997.1; = p.A678S on NM_002956.2) | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL4A2 | c.2959A>T p.K987* | Nonsense Mutation (SNP) | VAF 35/125 reads (28%) | called by muse, mutect2, varscan2
- CRELD1 | c.501_503delinsT p.Q168Vfs*2 | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | called by pindel, varscan2*
- CSMD1 | c.2720G>T p.S907I (on ENST00000520002; = p.S906I on NM_033225.6) | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DGCR2 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC1H1 | c.9835A>T p.K3279* | Nonsense Mutation (SNP) | VAF 106/372 reads (28%) | called by muse, mutect2
- ELP3 | c.1187T>A p.I396K | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHB3 | c.1496C>A p.S499Y | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ERMAP | c.1214del p.N405Tfs*5 | Frame Shift Del (DEL) | VAF 35/164 reads (21%) | called by mutect2, pindel, varscan2
- GOLGA8H | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 187/776 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GRIN2D | c.651C>A p.H217Q | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- HDHD5 | c.637C>G p.L213V (on ENST00000336737 / NM_033070.3; = p.L183V on NM_017829.5) | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- HIP1R | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF8 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT2A | c.2306T>C p.I769T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LIN54 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC4B | c.532T>A p.F178I | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MUC5B | c.7784C>A p.T2595N | Missense Mutation (SNP) | VAF 141/499 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- MYH3 | c.2963A>T p.E988V | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MYH3 | c.2962G>T p.E988* | Nonsense Mutation (SNP) | VAF 77/278 reads (28%) | called by muse, mutect2, varscan2
- NELL2 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- NEO1 | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- OPTN | c.49_51del p.S17del | In Frame Del (DEL) | VAF 66/350 reads (19%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1450A>T p.K484* | Nonsense Mutation (SNP) | VAF 64/147 reads (44%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PDE8B | c.445T>C p.W149R | Missense Mutation (SNP) | VAF 98/335 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RAD50 | c.3817_3821del p.F1273Gfs*7 | Frame Shift Del (DEL) | VAF 58/255 reads (23%) | called by mutect2, pindel, varscan2
- RECK | c.945T>A p.N315K | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RECK | c.1723A>T p.I575L | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNASE1 | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2
- SCAF4 | c.2341A>G p.I781V | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGCZ | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SLC35D2 | c.877del p.I293Ffs*5 | Frame Shift Del (DEL) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- SPIN3 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNGAP1 | c.2786A>T p.N929I | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TACR2 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TASOR2 | c.3746del p.N1249Ifs*2 | Frame Shift Del (DEL) | VAF 41/208 reads (20%) | called by mutect2, pindel, varscan2
- TBC1D12 | c.1283_1291del p.A428_R431delinsG | In Frame Del (DEL) | VAF 30/203 reads (15%) | called by mutect2, pindel, varscan2
- TBC1D9 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- THAP3 | c.381G>T p.M127I (on ENST00000054650 / NM_001195753.1; = p.M134I on NM_138350.3) | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMCO5A | c.383C>A p.T128K | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TOMM34 | c.795C>A p.Y265* | Nonsense Mutation (SNP) | VAF 67/216 reads (31%) | called by muse, mutect2, varscan2
- TTI2 | c.1139A>T p.H380L | Missense Mutation (SNP) | VAF 125/436 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC80 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 121/451 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP28 | c.2470C>G p.R824G | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY3 | c.8669del p.F2890Sfs*14 | Frame Shift Del (DEL) | VAF 40/173 reads (23%) | called by mutect2, pindel, varscan2
- WIZ | c.4203G>T p.M1401I (on ENST00000673675 / NM_001371589.1; = p.M306I on NM_021241.3) | Missense Mutation (SNP) | VAF 91/330 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ZC3H7A | c.1892A>T p.Q631L | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ZNF724 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- CAMKK1 | c.1509T>A p.A503= | Silent (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2, varscan2
- CEP76 | c.1401A>T p.G467= | Silent (SNP) | VAF 74/308 reads (24%) | called by muse, mutect2, varscan2
- COL24A1 | c.3324T>C p.I1108= | Silent (SNP) | VAF 37/185 reads (20%) | called by muse, mutect2, varscan2
- DLX6 | c.751C>T p.L251= | Silent (SNP) | VAF 96/412 reads (23%) | catalogued as rs1225120437; called by muse, mutect2, varscan2
- DQX1 | c.1123C>A p.R375= | Silent (SNP) | VAF 63/222 reads (28%) | catalogued as rs150420269; called by muse, mutect2, varscan2
- DYNC1H1 | c.9837A>G p.K3279= | Silent (SNP) | VAF 102/364 reads (28%) | called by muse, mutect2
- DYRK1A | c.816A>G p.A272= | Silent (SNP) | VAF 98/341 reads (29%) | catalogued as COSV100117899; called by muse, mutect2, varscan2
- EPHB2 | c.1476G>A p.T492= | Silent (SNP) | VAF 139/513 reads (27%) | catalogued as rs370664820; called by muse, mutect2, varscan2
- FCGBP | c.4830G>T p.T1610= | Silent (SNP) | VAF 87/680 reads (13%) | called by muse, mutect2, varscan2
- ITGAD | c.1269C>T p.A423= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV66760153; called by muse, mutect2, varscan2
- KAT6A | c.4482C>T p.V1494= | Silent (SNP) | VAF 72/212 reads (34%) | catalogued as COSV55904223; called by muse, mutect2, varscan2
- KCNH5 | c.1923C>T p.I641= | Silent (SNP) | VAF 53/141 reads (38%) | catalogued as COSV59768828; called by muse, mutect2, varscan2
- LRP1B | c.5394C>T p.A1798= | Silent (SNP) | VAF 84/245 reads (34%) | catalogued as rs754226036; called by muse, mutect2, varscan2
- OR4C6 | c.651G>T p.T217= | Silent (SNP) | VAF 80/344 reads (23%) | catalogued as rs776795154, COSV58605361, COSV58606268; called by muse, mutect2, varscan2
- PRMT7 | c.1095G>T p.V365= | Silent (SNP) | VAF 76/285 reads (27%) | called by muse, mutect2, varscan2
- SIKE1 | c.549A>G p.L183= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as rs963804130; called by muse, mutect2, varscan2
- SREBF1 | c.1512C>T p.A504= | Silent (SNP) | VAF 12/95 reads (13%) | called by muse, varscan2
- STAC2 | c.150G>A p.E50= | Silent (SNP) | VAF 52/246 reads (21%) | called by muse, mutect2, varscan2
- TCFL5 | c.744T>C p.A248= | Silent (SNP) | VAF 41/146 reads (28%) | called by muse, mutect2, varscan2
- TTC3 | c.5199A>G p.S1733= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV61294466; called by muse, mutect2, varscan2
- WTAP | c.996C>A p.L332= | Silent (SNP) | VAF 64/160 reads (40%) | called by muse, mutect2, varscan2
- ZBTB6 | c.627C>T p.D209= | Silent (SNP) | VAF 45/195 reads (23%) | called by muse, mutect2, varscan2
- ZNF616 | c.447T>A p.A149= | Silent (SNP) | VAF 62/267 reads (23%) | called by muse, varscan2
- B4GALT4 | c.*325A>T | 3'UTR (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- CCT6A | c.-33A>G | 5'UTR (SNP) | VAF 38/143 reads (27%) | called by muse, mutect2, varscan2
- CFAP410 | c.643-236C>T | Intron (SNP) | VAF 31/122 reads (25%) | catalogued as rs748118167; called by muse, mutect2, varscan2
- FGFR3 | c.*755C>A | 3'UTR (SNP) | VAF 45/186 reads (24%) | called by muse, mutect2, varscan2
- FNTA | c.783-47del | Intron (DEL) | VAF 10/48 reads (21%) | called by pindel, varscan2
- FSD1L | c.441+43dup | Intron (INS) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- IL12A | c.-25_-5del | 5'UTR (DEL) | VAF 33/186 reads (18%) | called by mutect2, pindel, varscan2
- KIF1B | c.2115+5993G>T | Intron (SNP) | VAF 61/238 reads (26%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+5994A>G | Intron (SNP) | VAF 62/236 reads (26%) | catalogued as rs376929489; called by muse, mutect2, varscan2
- MALRD1 | c.5030-2396G>T | Intron (SNP) | VAF 49/186 reads (26%) | called by muse, mutect2, varscan2
- NBAS | c.3257+539T>A | Intron (SNP) | VAF 29/166 reads (17%) | called by muse, mutect2, varscan2
- RHOQ | c.202-15459_202-15446del | Intron (DEL) | VAF 34/218 reads (16%) | called by mutect2, pindel
- SDK1 | c.1151-862T>A | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, varscan2
- SEPSECS | c.1211+37T>A | Intron (SNP) | VAF 67/201 reads (33%) | called by muse, mutect2, varscan2
- TMCO1 | c.*2051A>G | 3'UTR (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
